Surgical pathology report (de-identified scan), TCGA case TCGA-33-AASD, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-AASD-01A (Primary Tumor).

[page 1 of 3]
=====

INTERPRETATION AND DIAGNOSIS:

1. LUNG, RIGHT LOWER LOBE (WEDGE RESECTION): INFILTRATING SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (2.5 CM). THE VISCERAL PLEURA, BRONCHIAL MARGIN AND VASCULAR MARGIN ARE NEGATIVE FOR TUMOR. SCATTERED NECROTIZING GRANULOMAS. SPECIAL STAINS FOR MYCOBACTERIA (AFB) AND FUNGUS (GMS) ARE NEGATIVE.
2. LYMPH NODE, STATION 7 (BX.): ONE LYMPH NODE, NEGATIVE FOR TUMOR.
3. LYMPH NODE LEVEL 9 (BX.): ONE LYMPH NODE, NEGATIVE FOR TUMOR.

NOTE: The pathologic stage is T1 N0 MX.

*Electronic signature

=====

Clinical History:

YO WITH SQUAMOUS CARCINOMA OF THE LUNG

GROSS DESCRIPTION

(Continued on next page.)

ICD O-3

Carcinoma, squamous cell NOS
8070/3
Site @ Lung, lower lobe
C84.3
JN 5/28/14

[page 2 of 3]
SURGICAL
PATHOLOGY

PART #1: RIGHT LOWER LOBE WEDGE
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated right lower lobe wedge. It consists of an identifiable wedge of lung weighing 200 gms, and measures 12 x 9 x 4 cm. There is a palpable nodule present. The margin is stapled close, and there are grossly identifiable vessels and airways present at the margin. The tumor measures 2.5 cm and is located approximately the central portion of the specimen. It approaches within 1 cm of the stapled margin. The tumor is gray/white and firm, well demarcated from the surrounding low parenchyma. It approaches to within 1 cm of the inked pleural surface. The uninvolved lung parenchyma shows mucous plugging focally. The remaining parenchyma is beefy red and otherwise unremarkable. Representative sections are submitted.

SUMMARY OF SECTIONS:

1	- A	- 4	(VASCULAR AND BRONCHIAL MARGINS)
1	- B	- 3	(PARENCHYMAL SHAVES AT THE NEAREST STAPLE MARGIN)
1	- C	- 1	(TUMOR AT CLOSEST VISCERA PLEURA)
2	- D-E	- 1	EA. (TUMOR)
1	- F	- 1	(TUMOR AND ADJACENT BRONCHUS)
1	- G	- 1	(REPRESENTING TUMOR)
2	- H-I	- 1	EA. (PARENCHYMA REMOTE FROM TUMOR)
9	- TOTAL	- 9	

PART #2: STATION 7 LYMPH NODE
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated station VII, lymph node. It consists of black tan soft tissue measuring 2.7 x 1.5 x 0.6 cm. The specimen is bisected and one half of the lymph node is submitted for tumor bank, and future studies. The remainder is submitted for permanent sections.

SUMMARY OF SECTIONS:

1	- A	- 1
1	- TOTAL	- 1

(Continued on next page.)

[page 3 of 3]
SURGICAL
PATHOLOGY

PART #3: LYMPH NODE LEVEL 9
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated lymph node level IX. It consists of one piece of black tan soft tissue measuring 1 x 0.6 x 0.3 cm. The specimen is bisected and one half is submitted for tumor and future studies. The remaining half is submitted for permanent sections.

SUMMARY OF SECTIONS:

1 - A - 1
1 - TOTAL - 1

(End of Report)

printed

Source: NCI Genomic Data Commons file 700f9dc3-ad35-4598-8010-f96b3be6d84b (TCGA-33-AASD.00E9AF99-0DD2-447D-90F3-7F068E6C3E55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).